Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A5S3, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A5S3-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Resection of tumor

Tumor site: Esophagus

Tumor size: 4 x 2 x 1.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 0/2 positive for metastasis (Regional 0/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Involved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Distal

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Esophagus NOS C15.9
9/2/13

Source: NCI Genomic Data Commons file de8854e4-ac53-46b8-8620-938203765aef (TCGA-IG-A5S3.FDFE8CCD-7F18-454F-B4C4-A3F884D219CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).